Somatic mutation profile of tumor specimen TCGA-41-3393-01A (aliquot TCGA-41-3393-01A-01D-1353-08) from TCGA case TCGA-41-3393, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 81.9 years (29,904 days).
Specimen TCGA-41-3393-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e15cc281-464b-4306-bf0f-df2e7b325898.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-41-3393-10A (Blood Derived Normal), aliquot TCGA-41-3393-10A-01D-1353-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/388b3879-6f72-43e3-b4a5-19309808fbe4

The open-access MAF lists 74 somatic variants for this specimen: 57 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 15, Nonsense Mutation 5, Splice Site 2, Intron 2, Nonstop Mutation 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PORCN | c.1109G>A p.R370Q (on ENST00000326194 / NM_203475.3; = p.R359Q on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs387906723, COSV58225876; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM22 | c.1342G>A p.G448S | Missense Mutation (SNP) | VAF 47/195 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55992220; called by muse, mutect2, varscan2
- ADAM28 | c.890+1G>A p.X297_splice | Splice Site (SNP) | VAF 48/156 reads (31%) | catalogued as rs138768775; called by muse, mutect2, varscan2
- AFM | c.730A>G p.S244G | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV56922582; called by muse, mutect2, varscan2
- ALB | c.849C>G p.D283E | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55743329; called by muse, mutect2, varscan2
- AOAH | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 61/327 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs375296715; called by muse, mutect2, varscan2
- ARHGAP4 | c.2353C>T p.R785W | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs368238109; called by muse, mutect2
- ARSL | c.785C>T p.T262M | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1162739001, COSV66966097; called by muse, mutect2, varscan2
- BIRC3 | c.169T>C p.Y57H | Missense Mutation (SNP) | VAF 78/254 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54820349; called by muse, mutect2, varscan2
- C5AR2 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs771555144, COSV57257522; called by muse, mutect2, varscan2
- C6orf89 | c.952T>A p.Y318N (on ENST00000373685; = p.Y325N on NM_152734.4) | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62103487; called by muse, mutect2, varscan2
- CCDC42 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.206); catalogued as rs750192818, COSV53449957; called by muse, mutect2
- CPAMD8 | c.3142G>A p.V1048I (on ENST00000651564; = p.V1001I on NM_015692.5) | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs374273186; called by muse, mutect2, varscan2
- CSN2 | c.679T>C p.*227Qext*14 | Nonstop Mutation (SNP) | VAF 14/47 reads (30%) | catalogued as rs1425731445, COSV61992825; called by muse, varscan2
- CYSTM1 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs200630553, COSV55835905; called by muse, mutect2, varscan2
- DDC | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs777956037, CM149259, COSV63565591; called by muse, mutect2, varscan2
- DIDO1 | c.6119G>A p.R2040H | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.379); catalogued as rs143474883; called by muse, mutect2, varscan2
- DKKL1 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.067); catalogued as rs778820244, COSV55564023; called by muse, mutect2, varscan2
- DNAH12 | c.1172G>T p.W391L | Missense Mutation (SNP) | VAF 43/271 reads (16%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.631); catalogued as COSV60859130; called by muse, mutect2, varscan2
- DOCK11 | c.3128T>C p.I1043T | Missense Mutation (SNP) | VAF 106/457 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV52248851; called by muse, mutect2, varscan2
- ELSPBP1 | c.350C>T p.T117M | Missense Mutation (SNP) | VAF 42/201 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs145971035; called by muse, mutect2, varscan2
- ESCO1 | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 143/550 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs1172775395, COSV52523464; called by muse, varscan2
- FRMPD4 | c.2939C>T p.P980L | Missense Mutation (SNP) | VAF 77/304 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.08); catalogued as rs767817054, COSV66224671; called by muse, mutect2, varscan2
- GABRA5 | c.284C>A p.T95N | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59486220; called by muse, mutect2, varscan2
- HECTD1 | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67949576; called by muse, mutect2, varscan2
- HECW1 | c.1465G>T p.E489* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as COSV67841552; called by muse, mutect2, varscan2
- KCNA5 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52908892; called by muse, mutect2, varscan2
- KCNH7 | c.2512C>T p.R838* | Nonsense Mutation (SNP) | VAF 33/130 reads (25%) | catalogued as rs912483709, COSV59798523; called by muse, mutect2, varscan2
- LACRT | c.255A>G p.K85= | Splice Region (SNP) | VAF 87/295 reads (29%) | catalogued as COSV57688920; called by muse, mutect2, varscan2
- MKRN1 | c.1261G>T p.E421* | Nonsense Mutation (SNP) | VAF 20/147 reads (14%) | catalogued as COSV55438832; called by muse, mutect2, varscan2
- MMRN1 | c.3309T>G p.F1103L | Missense Mutation (SNP) | VAF 101/312 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53343478; called by muse, mutect2, varscan2
- MUC16 | c.3593C>T p.T1198M | Missense Mutation (SNP) | VAF 118/447 reads (26%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs145987902; called by muse, mutect2, varscan2
- MUC3A | c.7018A>G p.S2340G | Missense Mutation (SNP) | VAF 55/316 reads (17%) | SIFT deleterious, low confidence (0.03); catalogued as rs796578153, COSV60222128; called by muse, mutect2, varscan2
- MYF5 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 73/278 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs1269683532, COSV57354981, COSV57355677; called by muse, mutect2, varscan2
- NCBP2 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 70/216 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as COSV58318484; called by muse, mutect2, varscan2
- NETO1 | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.464); catalogued as rs1459765500, COSV55016516; called by muse, mutect2, varscan2
- PASD1 | c.1255G>A p.V419I | Missense Mutation (SNP) | VAF 135/466 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760827177, COSV64854548; called by muse, mutect2, varscan2
- PIWIL2 | c.1652G>A p.R551H | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as rs529353152, COSV63253505, COSV63254414; called by muse, mutect2, varscan2
- PLEKHG4 | c.1889C>T p.A630V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs775644209, COSV58574670; called by muse, mutect2, varscan2
- PRR23B | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as rs745919909, COSV61495049; called by muse, mutect2, varscan2
- PTPRT | c.4090C>A p.Q1364K | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV62028435; called by muse, mutect2, varscan2
- RFX5 | c.1418C>G p.S473* | Nonsense Mutation (SNP) | VAF 189/789 reads (24%) | catalogued as COSV51842014; called by muse, mutect2, varscan2
- RNF128 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55255218; called by muse, mutect2, varscan2
- SH3TC2 | c.895G>A p.G299S | Missense Mutation (SNP) | VAF 106/408 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1233598157, COSV60462941; called by muse, mutect2, varscan2
- SIGLECL1 | c.175T>A p.S59T | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.302); catalogued as COSV57065055; called by muse, mutect2, varscan2
- SLC6A17 | c.1144G>A p.V382I | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as rs759258693, COSV58997357; called by muse, mutect2, varscan2
- SLC7A3 | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.025); catalogued as rs1394534245, COSV53229657; called by muse, mutect2, varscan2
- SMARCD1 | c.874-1G>A p.X292_splice | Splice Site (SNP) | VAF 73/264 reads (28%) | catalogued as COSV67413288; called by muse, mutect2, varscan2
- SRC | c.832C>G p.Q278E | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.955); catalogued as COSV62441479; called by muse, mutect2
- TNKS2 | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 81/225 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV65417189; called by muse, mutect2, varscan2
- TNXB | c.5314C>T p.R1772* (on ENST00000647633; = p.R1525* on NM_019105.8 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as rs779751914, COSV64490253; called by muse, mutect2, varscan2
- TSR2 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV64309797; called by muse, mutect2, varscan2
- TTC21B | c.433C>A p.H145N | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV54636093; called by muse, mutect2, varscan2
- UPK1A | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs111275297; called by muse, mutect2, varscan2
- ZC3H12B | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756975795, COSV59048181; called by muse, mutect2, varscan2
- MAGEB6B | c.440A>T p.E147V | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- ZNF181 | c.1550_1555del p.Y517_K518del | In Frame Del (DEL) | VAF 40/208 reads (19%) | called by mutect2, varscan2
- ARSA | c.1506C>T p.C502= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV53351497; called by muse, mutect2, varscan2
- BARHL2 | c.417G>A p.T139= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs960204197, COSV64982196; called by muse, mutect2
- CACNA1B | c.5907A>T p.G1969= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV53152063; called by muse, mutect2, varscan2
- CAVIN2 | c.1197C>T p.Y399= | Silent (SNP) | VAF 70/246 reads (28%) | catalogued as rs756905753, COSV58426213; called by muse, mutect2, varscan2
- ENTHD1 | c.81C>T p.N27= | Silent (SNP) | VAF 84/270 reads (31%) | catalogued as rs146928757; called by muse, mutect2, varscan2
- GPR143 | c.1194C>G p.L398= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as COSV101102264, COSV66633338; called by muse, mutect2, varscan2
- MEGF6 | c.3810C>T p.C1270= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs544058443, COSV53896659; called by muse, mutect2, varscan2
- OR2J3 | c.372C>T p.D124= | Silent (SNP) | VAF 144/588 reads (24%) | catalogued as rs757035122, COSV65849796; called by muse, mutect2, varscan2
- PTGR1 | c.873C>T p.V291= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as COSV53031205; called by muse, mutect2, varscan2
- RAB40A | c.177C>T p.D59= | Silent (SNP) | VAF 81/391 reads (21%) | catalogued as rs1332331893, COSV58490882; called by muse, mutect2, varscan2
- SEMA3D | c.276A>G p.L92= | Silent (SNP) | VAF 146/640 reads (23%) | catalogued as rs561234345, COSV52406683; called by muse, mutect2, varscan2
- SIGLEC1 | c.3417C>T p.V1139= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as rs1490897683, COSV52474396; called by muse, varscan2
- SLC9C1 | c.2610G>A p.P870= | Silent (SNP) | VAF 13/226 reads (6%) | catalogued as rs372137369; called by muse, mutect2
- ZC3HAV1 | c.864G>A p.A288= | Silent (SNP) | VAF 72/366 reads (20%) | catalogued as rs766936579, COSV54293855; called by muse, mutect2, varscan2
- ZNF75D | c.591T>C p.P197= | Silent (SNP) | VAF 76/417 reads (18%) | catalogued as COSV66133606; called by muse, mutect2, varscan2
- HDAC8 | c.738-9951A>T | Intron (SNP) | VAF 21/186 reads (11%) | catalogued as COSV101003237; called by muse, mutect2, varscan2
- TPRN | c.2074-41G>A | Intron (SNP) | VAF 40/153 reads (26%) | catalogued as rs752497825, COSV58809339; called by muse, mutect2, varscan2
